Gene-level copy-number profile of tumor specimen TCGA-OR-A5LM-01A from TCGA case TCGA-OR-A5LM, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 23.9 years (8,735 days).
Specimen TCGA-OR-A5LM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.2152e9c3-9720-40b8-8652-533ddb5d26fc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5LM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6e0a22fb-7018-47f5-89c7-cd644209f000

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 60; copy number 2: 2,108; copy number 3: 21,190; copy number 4: 8,618; copy number 5: 8,642; copy number 6: 2,028; copy number 7: 10,958; copy number 8: 1,253; copy number 9: 2,328; copy number 10: 2,510; copy number 12: 101; copy number 13: 1; copy number 14: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5LM-01A-11D-A29H-01): tumor purity 0.76, ploidy 4.73, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 17,169 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–2,462,942, 89 genes, copy number 12 (broad region; genes not listed).
- chr4:2,463,797–2,464,124, 1 gene, copy number 12: AL645924.1.
- chr4:11,469,250–11,478,196, 1 gene, copy number 13 (within-gene range 6–13): AC025539.1.
- chr4:33,775,498–42,391,651, 133 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr4:45,995,119–180,574,027, 1,786 genes, copy number 7 (broad region; genes not listed).
- chr4:182,631,454–190,092,279, 168 genes, copy number 7 (broad region; genes not listed).
- chr5:58,198–181,342,213, 2,985 genes, copy number 7–14 (broad region; genes not listed).
- chr6:2,987,987–3,021,850, 1 gene, copy number 9 (within-gene range 2–9): NQO2.
- chr6:3,023,142–3,057,357, 6 genes, copy number 9: HTATSF1P2, AL133351.4, AL133351.3, FAM136BP, SERPINB8P1, AL031963.2.
- chr6:3,068,045–3,068,894, 1 gene, copy number 9: AL031963.3.
- chr6:4,079,206–5,066,982, 24 genes, copy number 8–12: C6orf201, ECI2, AL136309.3, ECI2-DT, AL136309.2, AL136309.1, AL162718.1, AL159166.1, AL162718.3, RNA5SP202, AL162718.2, LINC02533, AL133393.1, AL034376.1, KU-MEL-3, PSMC1P11, CDYL, AL356747.1, CDYL-AS1, AL359643.1, RPP40, LYRM4-AS1, AL359643.2, AL139094.1.
- chr6:7,590,198–11,138,733, 55 genes, copy number 9 (within-gene range 2–9): SNRNP48, AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1, AL355499.1, AL355499.2, AL359378.1, SLC35B3, HULC, AL161437.1, AL137220.1, OFCC1, AL136226.1, AL354868.1, RNU6ATAC21P, AL138885.1, TFAP2A, TFAP2A-AS2, TFAP2A-AS1, AL138885.2, AL138885.3, LINC00518, MIR5689HG, MIR5689, MRPL48P1, LINC02522, GCNT2, AL139039.3, AL139039.1, AL139039.2, GCNT2P1, AL358777.3, C6orf52, Y_RNA, PAK1IP1, TMEM14C, AL024498.1, TMEM14B, AL024498.2, RNA5SP203, MAK, GCM2, AL357497.1, SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1.
- chr6:21,664,185–24,426,194, 24 genes, copy number 8 (within-gene range 5–8): CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1, AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58, NRSN1, FO393410.1, DCDC2, KAAG1, RNU6-391P, MRS2.
- chr6:25,962,802–28,732,904, 175 genes, copy number 8 (broad region; genes not listed).
- chr6:31,083,010–32,178,096, 134 genes, copy number 8 (broad region; genes not listed).
- chr6:35,943,516–37,535,616, 48 genes, copy number 8 (within-gene range 5–8): SLC26A8, DPRXP2, MAPK14, Z95152.1, MAPK13, Z84485.1, BRPF3, PNPLA1, BNIP5, ETV7, ETV7-AS1, PXT1, KCTD20, RN7SL502P, STK38, RN7SL748P, SRSF3, MIR3925, RNU1-88P, Y_RNA, PANDAR, LAP3P2, CDKN1A, DINOL, RAB44, Z85996.1, CPNE5, Z85996.2, Z85996.3, PPIL1, C6orf89, AL122034.1, PI16, MTCH1, FGD2, COX6A1P2, RPL12P2, PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520.
- chr6:45,880,827–46,491,972, 8 genes, copy number 9: CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1.
- chr6:67,625,356–68,242,364, 8 genes, copy number 8 (within-gene range 4–8): Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1.
- chr6:68,635,282–69,389,506, 1 gene, copy number 8 (within-gene range 4–8): ADGRB3.
- chr7:70,972–77,995,171, 1,488 genes, copy number 7 (broad region; genes not listed).
- chr12:66,767–133,214,832, 3,050 genes, copy number 8–9 (broad region; genes not listed).
- chr16:11,555–70,801,160, 2,048 genes, copy number 7 (broad region; genes not listed).
- chr16:71,281,389–90,222,851, 508 genes, copy number 7 (broad region; genes not listed).
- chr19:94,062–58,605,223, 2,981 genes, copy number 7 (broad region; genes not listed).
- chr20:87,250–13,300,651, 274 genes, copy number 7 (broad region; genes not listed).
- chr20:13,995,369–16,053,197, 1 gene, copy number 7 (within-gene range 4–7): MACROD2.
- chr20:14,522,081–64,313,132, 1,171 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 60. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
